Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A71B, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A71B-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Alveolar NOS
803.9
JW 8/9/13

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Alveolar ridge

1 - "Floor of the mouth and mandible specimen and right neck dissection levels I, II and III":

- Moderately differentiated squamous cell carcinoma involving skin and adjacent soft tissue.
- Tumor size: 5.0 cm
- lymphovascular invasion: absent
- Perineural invasion: absent
- Surgical margins (skin, mucosal and soft tissue) uninvolved by carcinoma.
- Eleven lymph nodes with no evidence of metastatic carcinoma (0/11).
- Osseous tissue involved by carcinoma.
- Osseous margin uninvolved by carcinoma.
- Salivary gland: absence of neoplasia.

HPV Discrepancy		✓

Source: NCI Genomic Data Commons file 0032536f-8667-4082-a190-dd7fcf1921b6 (TCGA-UF-A71B.62D06D71-D9FA-4CDA-9873-9D6A98DCAA60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).